Somatic mutation profile of tumor specimen TCGA-EM-A1YC-01A (aliquot TCGA-EM-A1YC-01A-11D-A14W-08) from TCGA case TCGA-EM-A1YC, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 71.6 years (26,143 days).
Specimen TCGA-EM-A1YC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1146fb0-76cd-4d1c-b38d-5b3f5af9ba03.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A1YC-11A (Solid Tissue Normal), aliquot TCGA-EM-A1YC-11A-11D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/570581e1-cc5c-4a2b-b855-5c7e1fe79b93

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 6, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL2 | c.2754C>G p.H918Q (on ENST00000370717 / NM_001366005.1; = p.H905Q on NM_012302.4) | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs779978389, COSV54670044; called by muse, mutect2, varscan2
- ATM | c.8535G>T p.W2845C | Missense Mutation (SNP) | VAF 103/191 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM0910475, COSV53729192; called by muse, mutect2, varscan2
- EGFL6 | c.653T>C p.I218T | Missense Mutation (SNP) | VAF 21/224 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs151014946, COSV63634064; called by muse, mutect2
- HAPLN1 | c.723G>T p.W241C | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV57148358; called by muse, mutect2, varscan2
- RUFY2 | c.216T>A p.D72E | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV61191292; called by muse, mutect2
- TMEM35A | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); catalogued as COSV54503173; called by muse, mutect2, varscan2
- AKR1D1 | c.822C>T p.S274= | Silent (SNP) | VAF 7/181 reads (4%) | catalogued as COSV54337836; called by muse, mutect2
- CCDC178 | c.2418A>G p.T806= (on ENST00000383096 / NM_001105528.3; = p.T768= on NM_198995.3) | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV55776206; called by muse, mutect2, varscan2
- CDCP1 | c.1315C>T p.L439= | Silent (SNP) | VAF 9/138 reads (7%) | catalogued as COSV56105904; called by muse, mutect2
- FLOT1 | c.711C>G p.A237= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV52544035, COSV99458071; called by muse, mutect2, varscan2
- INPPL1 | c.1809C>T p.F603= | Silent (SNP) | VAF 7/118 reads (6%) | catalogued as COSV53356120; called by muse, mutect2
